Surgical pathology report (de-identified scan), TCGA case TCGA-19-4068, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-4068-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

*** Amended ***

Addendum Present

TCGA - 19 - 4068

FINAL DIAGNOSIS

A., C. LEFT OCCIPITAL LOBE OF BRAIN, TUMOR, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: Both focal microvascular proliferation and coagulative tumor necrosis are identified.

B. LEFT PARIETAL LESION, BIOPSY:
-- INFILTRATING GLIOMA.

Electronically Signed Out By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Amendment Comments:

Amended: [REDACTED]

Reason: Editorial Change

Amended to include additional part C.

Previous Signout Date: [REDACTED]

Intraoperative Consult Diagnosis

A. Touch imprint: Malignant astrocytoma.

B. Touch imprint/microscopic: Infiltrating glioma.

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]

Status: Signed Out

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Addendum Diagnosis

The slides from this specimen were sent at the patient's or their clinician's request to [REDACTED] for review. A copy of their report is retained in the Department of Anatomic Pathology files.

Electronically Signed Out By

Clinical History:

left occipital tumor

Specimens Submitted As:

A:LEFT OCCIPITAL BRAIN TUMOR

B:LEFT PARIETAL LESION

C:LEFT OCCIPITAL TUMOR

[page 2 of 2]
Gross Description:

A. Received fresh for intraoperative diagnosis, labeled with the patient's name, hospital number, and "left occipital brain tumor" are two tan -- red, soft, irregular fragments of tissue, 1.0 x 0.7 x 0.7 cm and 0.9 x 0.8 x 0.6 cm. A touch prep was performed on both fragments of tissue. The remaining specimen was entirely submitted in two cassettes.

B. Received fresh for intraoperative diagnosis, labeled with the patient's name, hospital number, and "left parietal lesion" are two tan -- red, soft, irregular fragments of tissue, 0.6 x 0.5 x 0.3 cm and 0.5 x 0.4 x 0.3 cm. A representative section of both fragments of tissue was frozen for intraoperative diagnosis. A touch imprint of both fragments was performed for intraoperative diagnosis. The specimen is submitted entirely two cassettes.

C: Received in formalin, labeled with the patient's name and number, are multiple white-tan to red-brown irregular soft tissue fragments measuring 3.2 x 1.5 x 0.5 cm in aggregate. Submitted in toto in two cassettes.

Cassette summary:

A	1	1.0 x 0.7 x 0.7 cm mass, submitted entirely
	2	0.9 x 0.8 x 0.6 cm mass, submitted entirely
B	1FS	representative sections of both fragments of tissue, frozen sections
	2	remainder of tissue

Source: NCI Genomic Data Commons file 33d74238-048f-49b0-89ec-871b2320a5d9 (TCGA-19-4068.52DD5F36-FFF5-4A3F-AE34-E27D7944808D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).